Somatic mutation profile of tumor specimen 0DF853 from CCDI case PBBRUB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.9 years (2,879 days).
Specimen 0DF853: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57a49785-97ab-4630-a6db-52276b02f789.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF854 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc04c323-78aa-42ec-9eda-3a7a0b1bb33a

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 3'UTR 2, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CROCC2 | c.3229G>C p.E1077Q | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV99069067; called by muse, mutect2, varscan2
- EPB42 | c.1372C>T p.R458C (on ENST00000441366 / NM_001114134.2; = p.R488C on NM_000119.3) | Missense Mutation (SNP) | VAF 74/619 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.157); catalogued as rs1186857808; called by muse, mutect2, varscan2
- FAT2 | c.9740G>A p.G3247D | Missense Mutation (SNP) | VAF 20/600 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.639); catalogued as rs1407506794; called by muse, mutect2
- KIF5A | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 173/715 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1060502524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF144A | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 128/833 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs753241451; called by muse, mutect2, varscan2
- APEH | c.1478G>T p.S493I | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- CACNA1C | c.6329dup p.V2111Gfs*86 (on ENST00000399634 / NM_001167625.1; = p.V2040Gfs*86 on NM_000719.7) | Frame Shift Ins (INS) | VAF 22/146 reads (15%) | called by mutect2, varscan2
- CROCC2 | c.3228C>A p.D1076E | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.105); called by muse, varscan2
- MUC5AC | c.7499C>G p.T2500R | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.49); called by muse, mutect2, varscan2
- RASSF6 | c.220C>A p.L74M (on ENST00000342081 / NM_201431.2; = p.L42M on NM_177532.5) | Missense Mutation (SNP) | VAF 107/581 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- RIC3 | c.898C>T p.P300S (on ENST00000309737 / NM_001206671.4; = p.P299S on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/753 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.036); called by muse, mutect2
- IRF2BP2 | c.669C>T p.S223= | Silent (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- MXD1 | c.291A>G p.L97= | Silent (SNP) | VAF 82/566 reads (14%) | called by muse, mutect2
- LCOR | c.*2576G>C | 3'UTR (SNP) | VAF 27/224 reads (12%) | called by muse, mutect2, varscan2
- WLS | c.*11C>T | 3'UTR (SNP) | VAF 29/204 reads (14%) | catalogued as rs368139849; called by muse, mutect2, varscan2
